Somatic mutation profile of tumor specimen MMRF_1355_5_BM_CD138pos (aliquot MMRF_1355_5_BM_CD138pos_T1_KHS5U_L08846) from MMRF case MMRF_1355, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 75.0 years (27,387 days).
Specimen MMRF_1355_5_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69984600-e335-4f30-a4b5-3e3809e005da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1355_2_PB_Whole (Blood Derived Normal), aliquot MMRF_1355_2_PB_Whole_C1_KAS5U_L01938; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/104c3ad2-2db6-427f-bc32-cb976ed0530c

The open-access MAF lists 4 somatic variants for this specimen: 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 2, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BTBD9 | c.*652C>T | 3'UTR (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- GALT | c.83-78T>C | Intron (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- RMDN2 | c.453-21055C>T | Intron (SNP) | VAF 4/77 reads (5%) | catalogued as rs956357212; called by muse, mutect2
- SH2D6 | n.493G>A | RNA (SNP) | VAF 3/46 reads (7%) | catalogued as rs1350533001, COSV61063636; called by muse, mutect2
